Somatic mutation profile of tumor specimen MP2PRT-PAPYSK-TMP1-A (aliquot MP2PRT-PAPYSK-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPYSK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,640 days).
Specimen MP2PRT-PAPYSK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b934313-998c-4d8f-bc86-db6648b6f430.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPYSK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPYSK-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fef3f7c-67f0-4505-bf22-77af0ecb3774

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 103/317 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs773108471; called by muse, mutect2, varscan2
- AMOTL2 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 42/521 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51438736; called by muse, mutect2
- ANKS1A | c.2606G>A p.R869Q | Missense Mutation (SNP) | VAF 123/551 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs769104342, COSV64464116; called by muse, mutect2, varscan2
- COG1 | c.2546T>C p.I849T | Missense Mutation (SNP) | VAF 91/395 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138801104; called by muse, mutect2, varscan2
- DIDO1 | c.5572G>A p.A1858T | Missense Mutation (SNP) | VAF 108/344 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs764287999; called by muse, varscan2
- DIRAS2 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768090981, COSV65370502; called by muse, mutect2, varscan2
- FGF3 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 184/520 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782512706; called by muse, varscan2
- JADE3 | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 171/428 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54467042; called by muse, mutect2, varscan2
- MTMR7 | c.83T>C p.L28S | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761801071; called by muse, mutect2, varscan2
- PCDHB8 | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 233/2872 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as COSV50759783, COSV50767627, COSV99176886; called by muse, mutect2
- PLCH1 | c.4993G>A p.V1665I (on ENST00000340059 / NM_001130960.2; = p.V1657I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/311 reads (40%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs780237556, COSV58189362; called by muse, mutect2, varscan2
- UGT2B7 | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 93/402 reads (23%) | catalogued as rs770419807, COSV59441898; called by muse, mutect2, varscan2
- IGHD3-9 | c.25_*1delinsCT | Nonstop Mutation (DEL) | VAF 78/138 reads (57%) | called by pindel, varscan2*
- MUC5B | c.3670G>C p.D1224H | Missense Mutation (SNP) | VAF 138/388 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- NKX1-1 | c.273C>A p.N91K | Missense Mutation (SNP) | VAF 156/679 reads (23%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- WDR87 | c.3848G>T p.S1283I | Missense Mutation (SNP) | VAF 105/308 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQCA1L | c.2019C>T p.T673= | Silent (SNP) | VAF 156/443 reads (35%) | called by muse, mutect2, varscan2
- SLIT3 | c.3093C>T p.C1031= | Silent (SNP) | VAF 86/232 reads (37%) | catalogued as rs775114129, COSV100265171; called by muse, varscan2
- SRRM4 | c.570G>A p.S190= | Silent (SNP) | VAF 163/453 reads (36%) | catalogued as rs373113033; called by muse, mutect2, varscan2
- TBC1D32 | c.3609C>T p.D1203= | Silent (SNP) | VAF 84/365 reads (23%) | called by muse, mutect2, varscan2
